CCDI case PBCGIW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Meninges.
https://portal.gdc.cancer.gov/cases/8258a943-5a53-41d4-8213-78f1703d39c2

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Spinal meninges; Age at diagnosis: 12.6 years (4,587 days).

Biospecimens (3 samples)
- Sample 0DS8G8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS8GK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS8GT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
